Gene-level copy-number profile of tumor specimen ALCH-AEQA-TTP1-A from ALCHEMIST case ALCH-AEQA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.0 years (27,406 days).
Specimen ALCH-AEQA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 155421c2-75b6-4c63-904d-611785f05e21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEQA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/97a045b2-8406-4ee6-89d3-10114be283b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 9,855; copy number 2: 45,981; copy number 3: 3,040; copy number 4: 16; copy number 5: 2; copy number 6: 1; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,140,982–105,168,824, 2 genes (within-gene range 0–2): JAG2, MIR6765.
- chr15:44,962,830–44,971,178, 2 genes: RNU6-1332P, AC090888.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,446,601–43,479,534, 3 genes, copy number 5–6 (within-gene range 5–17): LINC00319, LINC00313, AP001048.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 2–9): GATD3A.
- chr22:18,873,543–18,894,407, 2 genes, copy number 9: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 7,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
